Somatic mutation profile of tumor specimen C3N-03449-01 (aliquot CPT0225900006) from CPTAC case C3N-03449, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.6 years (21,763 days).
Specimen C3N-03449-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8f6bdab-7dc0-4c99-bea6-039b8a13123b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03449-31 (Blood Derived Normal), aliquot CPT0225920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a2d77e7-82f8-43fa-984a-8697c226768e

The open-access MAF lists 54 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, 3'UTR 2, Nonsense Mutation 2, Intron 2, In Frame Del 1, RNA 1, 3'Flank 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 54/270 reads (20%) | catalogued as rs397514641, CM000774, COSV62197492; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 99/287 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 88/156 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs748408152, COSV67231399; called by muse, mutect2, varscan2
- CRTAC1 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 75/109 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs147584793; called by muse, mutect2, varscan2
- ELFN2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs563093626; called by muse, mutect2, varscan2
- OR2A14 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV68718074; called by muse, mutect2, varscan2
- OR5A1 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as rs755957715, COSV57377644; called by muse, mutect2, varscan2
- PC | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 40/804 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs780682688, COSV63081452; called by muse, mutect2
- PTEN | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 99/135 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as CD110183, CM124223, COSV64288507; called by muse, mutect2, varscan2
- SCN9A | c.5705G>A p.R1902H (on ENST00000303354; = p.R1891H on NM_002977.3) | Missense Mutation (SNP) | VAF 165/348 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs180949263, COSV57611089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHFL | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1490610484; called by muse, mutect2
- TACR3 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as COSV59208675; called by muse, mutect2, varscan2
- TOR4A | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1206156089; called by muse, mutect2
- TTLL8 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780536224, COSV56722051, COSV99838287; called by muse, mutect2, varscan2
- UNC13C | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.141); catalogued as rs199861324; called by muse, mutect2, varscan2
- ZNF492 | c.182del p.N61Ifs*6 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs754633801; called by mutect2, varscan2
- C1orf167 | c.1743_1751del p.P583_G585del | In Frame Del (DEL) | VAF 45/121 reads (37%) | called by mutect2, pindel, varscan2
- CHD4 | c.3761A>G p.D1254G (on ENST00000357008 / NM_001363606.2; = p.D1267G on NM_001273.5) | Missense Mutation (SNP) | VAF 155/390 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CRISP1 | c.230T>A p.I77N | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DENND1C | c.1360T>C p.S454P | Missense Mutation (SNP) | VAF 142/329 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- FAM205A | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 168/245 reads (69%) | called by muse, mutect2, varscan2
- FBXL7 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 29/413 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HMCN1 | c.11689C>A p.P3897T | Missense Mutation (SNP) | VAF 113/405 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV2D-29 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 303/631 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- JADE3 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT81 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 203/587 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MGAM2 | c.4097G>A p.S1366N | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MGST1 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MROH7 | c.3839G>A p.G1280E | Missense Mutation (SNP) | VAF 158/433 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- MYH13 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 216/454 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NHSL1 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 136/193 reads (70%) | SIFT tolerated (0.48); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OPRD1 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- OR5I1 | c.814A>C p.T272P | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- P3H2 | c.2030A>T p.E677V | Missense Mutation (SNP) | VAF 143/348 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCDH11X | c.3469T>C p.S1157P | Missense Mutation (SNP) | VAF 51/425 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TMPRSS11B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZFR2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ACSM5 | c.1101C>T p.Y367= | Silent (SNP) | VAF 169/438 reads (39%) | catalogued as rs369835056; called by muse, mutect2, varscan2
- CCDC144A | c.213G>A p.Q71= | Silent (SNP) | VAF 148/686 reads (22%) | called by muse, mutect2, varscan2
- KDM6B | c.231T>G p.A77= | Silent (SNP) | VAF 194/734 reads (26%) | called by muse, mutect2, varscan2
- MRGPRX2 | c.705C>T p.C235= | Silent (SNP) | VAF 102/245 reads (42%) | catalogued as rs769146454; called by muse, mutect2, varscan2
- NSD3 | c.1671G>A p.Q557= | Silent (SNP) | VAF 85/232 reads (37%) | catalogued as rs1169445602; called by muse, mutect2, varscan2
- OR2F1 | c.729T>G p.S243= | Silent (SNP) | VAF 69/273 reads (25%) | called by muse, mutect2, varscan2
- PPP4R4 | c.1548C>G p.V516= | Silent (SNP) | VAF 71/179 reads (40%) | catalogued as COSV58557878; called by muse, mutect2, varscan2
- SLC35G3 | c.499C>T p.L167= | Silent (SNP) | VAF 293/1048 reads (28%) | called by muse, mutect2, varscan2
- SLC49A3 | c.873C>T p.F291= (on ENST00000404286 / NM_001294341.2; = p.F290= on NM_032219.4) | Silent (SNP) | VAF 90/198 reads (45%) | catalogued as rs1413108871; called by muse, mutect2, varscan2
- TTN | c.16329G>A p.T5443= (on ENST00000591111; = p.T4516= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/151 reads (62%) | catalogued as rs748617936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL27A1 | c.2269-233G>A | Intron (SNP) | VAF 14/214 reads (7%) | catalogued as rs1001801800, COSV61924491; called by muse, mutect2
- GTF2IRD2P1 | n.1548C>T | RNA (SNP) | VAF 192/664 reads (29%) | called by muse, mutect2, varscan2
- IL13RA2 | c.-6G>A | 5'UTR (SNP) | VAF 92/125 reads (74%) | catalogued as rs1248265122; called by muse, mutect2, varscan2
- PPFIBP1 | c.-36+21240C>T | Intron (SNP) | VAF 67/217 reads (31%) | catalogued as rs745679378; called by muse, mutect2, varscan2
- RNU6-713P | chr12:40550158 G>A | 3'Flank (SNP) | VAF 61/176 reads (35%) | catalogued as rs553136078; called by muse, mutect2, varscan2
- TMEM135 | c.*7481A>G | 3'UTR (SNP) | VAF 91/314 reads (29%) | called by muse, mutect2, varscan2
- YIPF5 | c.*1990_*1994del | 3'UTR (DEL) | VAF 21/81 reads (26%) | catalogued as rs1369313227; called by mutect2, pindel, varscan2
